Somatic mutation profile of tumor specimen 0DRKKP from CCDI case PBCGNN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 5.9 years (2,150 days).
Specimen 0DRKKP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c455a106-407a-4b74-8d9a-8db66dec86ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRKKW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94824172-60ff-4b1a-b72b-ba72258e3314

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Intron 2, Frame Shift Ins 2, In Frame Del 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 271/501 reads (54%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 342/557 reads (61%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C7 | c.1616C>T p.T539M | Missense Mutation (SNP) | VAF 218/493 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.828); catalogued as rs761156913, COSV57474096; called by muse, mutect2, varscan2
- HOXA2 | c.304_306del p.K102del | In Frame Del (DEL) | VAF 100/226 reads (44%) | catalogued as rs773732762; called by pindel, varscan2
- KSR2 | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 84/188 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as COSV56680206; called by muse, mutect2, varscan2
- NSMCE1 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 147/299 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs765413529; called by muse, mutect2, varscan2
- OR6F1 | c.73C>A p.L25I | Missense Mutation (SNP) | VAF 128/820 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57469697; called by mutect2, varscan2
- PDIA5 | c.1475G>T p.R492L | Missense Mutation (SNP) | VAF 180/357 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV60249024; called by muse, mutect2, varscan2
- PDZD2 | c.7183C>T p.R2395C | Missense Mutation (SNP) | VAF 207/482 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747639151; called by muse, mutect2, varscan2
- PPM1D | c.1535dup p.N512Kfs*16 | Frame Shift Ins (INS) | VAF 273/602 reads (45%) | catalogued as rs763475304; called by mutect2, varscan2
- WDR75 | c.749T>C p.M250T | Missense Mutation (SNP) | VAF 112/293 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs750383389; called by muse, mutect2, varscan2
- XKR7 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs748529332, COSV73812898; called by muse, mutect2, varscan2
- CARMIL3 | c.3944T>A p.L1315Q | Missense Mutation (SNP) | VAF 20/438 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- IQCA1 | c.1227dup p.D410Rfs*2 | Frame Shift Ins (INS) | VAF 128/334 reads (38%) | called by mutect2, pindel, varscan2
- RNF138 | c.669+2dup p.X223_splice | Splice Site (INS) | VAF 63/166 reads (38%) | called by mutect2, pindel, varscan2
- ERCC4 | c.2430G>A p.A810= | Silent (SNP) | VAF 157/312 reads (50%) | catalogued as rs770255135; called by muse, mutect2, varscan2
- NFKBIE | c.1155C>T p.L385= (on ENST00000275015; = p.L246= on NM_004556.3) | Silent (SNP) | VAF 225/500 reads (45%) | catalogued as COSV51488804, COSV51491862; called by muse, mutect2, varscan2
- RNF213 | c.14043C>T p.I4681= | Silent (SNP) | VAF 147/335 reads (44%) | catalogued as COSV100301899; called by muse, mutect2, varscan2
- RYR2 | c.3117T>C p.D1039= | Silent (SNP) | VAF 47/891 reads (5%) | called by muse, mutect2
- FAM76A | c.837+11_837+12del | Intron (DEL) | VAF 26/252 reads (10%) | called by pindel, varscan2
- HOXB3 | c.*59G>T | 3'UTR (SNP) | VAF 76/172 reads (44%) | called by muse, mutect2, varscan2
- TLE6 | c.741-41C>A | Intron (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
